CCDI case PBCGAA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/e6577f46-7817-4d5e-a4f2-6599a3775272

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 9.3 years (3,386 days).

Biospecimens (2 samples)
- Sample 0DR538: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR53E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
